Gene-level copy-number profile of tumor specimen TCGA-D7-6518-01A from TCGA case TCGA-D7-6518, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 75.5 years (27,594 days).
Specimen TCGA-D7-6518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.487d6c9e-bdd7-473f-9bf4-bd70987379b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6518-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f8aa25aa-482a-4247-973d-d176cdf60ec6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,818; copy number 2: 41,006; copy number 3: 4,358; copy number 4: 6,021; copy number 5: 275; copy number 6: 168; copy number 8: 44; copy number 9: 91; copy number 11: 2; copy number 21: 3; copy number 22: 9; copy number 31: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6518-01A-11D-1799-01): tumor purity 0.35, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,091,245, 1 gene: RPS26P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 614 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:40,240,167–56,233,330, 197 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr8:111,376,639–113,950,998, 14 genes, copy number 5–11: LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA.
- chr8:119,873,717–120,050,918, 1 gene, copy number 5 (within-gene range 3–5): DEPTOR.
- chr8:120,052,180–121,119,754, 10 genes, copy number 5: AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1.
- chr8:122,414,332–122,428,551, 1 gene, copy number 5: SMILR.
- chr8:123,288,355–130,017,129, 116 genes, copy number 5–8 (broad region; genes not listed).
- chr8:130,069,541–130,084,768, 2 genes, copy number 5: RNU6-1255P, ASAP1-IT2.
- chr13:108,335,354–110,763,133, 34 genes, copy number 21–31 (within-gene range 4–31): AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107.
- chr20:28,563,850–36,646,196, 239 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,620. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
